Gene-level copy-number profile of tumor specimen TCGA-13-2057-01A from TCGA case TCGA-13-2057, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,554 days).
Specimen TCGA-13-2057-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b1f90a25-d938-416b-948d-f5767460867a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-2057-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/540863bc-1016-4be2-8ea6-b27b8859e610

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,175; copy number 3: 9,321; copy number 4: 19,414; copy number 5: 9,581; copy number 6: 4,955; copy number 7: 7,471; copy number 8: 4,612; copy number 9: 926; copy number 10: 1,012; copy number 11: 58; copy number 14: 618; copy number 15: 110; copy number 16: 60; copy number 17: 25; copy number 18: 79; copy number 19: 2; copy number 20: 42; copy number 21: 16; copy number 22: 81; copy number 29: 66; copy number 31: 174; copy number 32: 2; copy number 33: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-2057-01A-02D-1043-01): tumor purity 0.71, ploidy 4.92, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,289 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–39,487,177, 1 gene, copy number 10 (within-gene range 4–10): MACF1.
- chr1:39,154,164–43,968,022, 163 genes, copy number 10–16 (within-gene range 4–16) (broad region; genes not listed).
- chr1:87,620,803–88,685,204, 1 gene, copy number 11 (within-gene range 4–11): PKN2-AS1.
- chr1:88,313,153–95,782,342, 163 genes, copy number 11–17 (within-gene range 4–17) (broad region; genes not listed).
- chr1:163,111,121–165,445,355, 27 genes, copy number 9 (within-gene range 8–9): RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG.
- chr1:227,518,738–241,802,133, 326 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr1:242,772,620–248,919,946, 192 genes, copy number 10 (broad region; genes not listed).
- chr2:38,814–13,609,168, 220 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr2:72,887,382–72,936,071, 3 genes, copy number 18–19: SPR, EMX1, AC012366.1.
- chr2:90,190,193–107,407,329, 333 genes, copy number 9 (broad region; genes not listed).
- chr2:107,529,292–107,556,499, 1 gene, copy number 9 (within-gene range 7–9): LINC01886.
- chr3:124,723,788–125,595,497, 24 genes, copy number 14 (within-gene range 7–14): AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11.
- chr3:164,171,471–184,780,720, 337 genes, copy number 9 (broad region; genes not listed).
- chr6:102,453,367–107,133,170, 51 genes, copy number 21–33: AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–126,258,355, 273 genes, copy number 9–33 (broad region; genes not listed).
- chr6:126,340,115–126,348,875, 1 gene, copy number 9: CENPW.
- chr8:59,137,372–59,137,502, 1 gene, copy number 9: AC087698.1.
- chr8:65,161,145–66,962,591, 35 genes, copy number 9 (within-gene range 4–9): LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24.
- chr12:66,767–27,824,382, 719 genes, copy number 10–18 (broad region; genes not listed).
- chr12:57,591,174–74,664,141, 311 genes, copy number 15–31 (broad region; genes not listed).
- chr19:21,800,480–24,163,425, 107 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
